Gene-level copy-number profile of tumor specimen TCGA-FD-A6TC-01A from TCGA case TCGA-FD-A6TC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 79.3 years (28,963 days).
Specimen TCGA-FD-A6TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2fe26260-ad96-492b-a7a3-a8ee56fe7982.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/31c9485d-4738-45b3-9521-d75d5e545463

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 507; copy number 2: 12,483; copy number 3: 24,172; copy number 4: 16,997; copy number 5: 2,176; copy number 6: 2,515; copy number 7: 266; copy number 8: 100; copy number 9: 389; copy number 13: 153; copy number 18: 14; copy number 20: 3; copy number 22: 2; copy number 26: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TC-01A-21D-A338-01): tumor purity 0.57, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:63,703,483–63,936,906, 3 genes: AC018846.1, LINC02165, AC092337.1.
- chr16:76,277,288–76,819,624, 1 gene (within-gene range 0–7): AC106741.1.
- chr16:76,469,508–77,980,107, 22 genes (within-gene range 0–3): SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1, AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 930 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:193,398,967–198,222,513, 171 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:24,537,332–27,662,883, 95 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:14,904,997–15,082,342, 1 gene, copy number 7 (within-gene range 2–7): CALCB.
- chr11:14,987,671–15,705,376, 6 genes, copy number 7: OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2.
- chr16:64,155,169–64,343,909, 3 genes, copy number 26: AC093536.2, AC012322.1, AC093536.1.
- chr16:65,861,112–76,560,757, 383 genes, copy number 7–22 (within-gene range 0–22) (broad region; genes not listed).
- chr16:76,287,630–76,287,739, 1 gene, copy number 7: RN7SKP233.
- chr16:86,331,632–86,515,422, 5 genes, copy number 8: LINC00917, AC092327.2, AC092327.1, FENDRR, FOXF1.
- chr16:87,383,953–87,945,202, 21 genes, copy number 9: MAP1LC3B, AC010531.3, ZCCHC14, AC105429.2, AC105429.1, AC092720.3, AC092720.1, AC092720.2, JPH3, AC010536.3, AC010536.1, KLHDC4, AC010536.2, AC126696.3, AC126696.1, SLC7A5, MIR6775, AC126696.2, CA5A, AC133539.1, AC127455.1.
- chr19:33,386,950–34,066,283, 10 genes, copy number 7 (within-gene range 3–7): PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20.
- chr20:18,059,493–19,722,926, 42 genes, copy number 9: AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1.
- chr20:30,294,550–35,674,544, 186 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:55,408,898–56,005,519, 6 genes, copy number 9: LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4.

Autosomal genes at a single copy (total copy number 1): 507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
